Somatic mutation profile of tumor specimen TCGA-G6-A8L6-01A (aliquot TCGA-G6-A8L6-01A-11D-A36X-10) from TCGA case TCGA-G6-A8L6, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 55.6 years (20,306 days).
Specimen TCGA-G6-A8L6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55b68601-79e6-4447-82a5-c66ddc43b9b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G6-A8L6-10A (Blood Derived Normal), aliquot TCGA-G6-A8L6-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e854126e-87a6-4316-8ab5-806aa22c3a71

The open-access MAF lists 66 somatic variants for this specimen: 54 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Frame Shift Ins 6, Frame Shift Del 4, Nonsense Mutation 4, Splice Site 2, In Frame Del 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM1 | c.145T>G p.F49V | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99532507; called by muse, mutect2, varscan2
- AF196969.1 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | catalogued as COSV52141945, COSV99339290; called by muse, mutect2, varscan2
- ANKRD1 | c.733C>T p.L245F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100865285; called by muse, mutect2, varscan2
- ANKS1B | c.1668C>A p.C556* | Nonsense Mutation (SNP) | VAF 28/202 reads (14%) | catalogued as rs775492872, COSV100242867; called by muse, mutect2, varscan2
- BPTF | c.811T>C p.C271R | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100074044; called by muse, mutect2, varscan2
- CAND1 | c.607G>C p.V203L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.197); catalogued as COSV101598261; called by muse, mutect2, varscan2
- CCKAR | c.34A>G p.S12G | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.376); catalogued as COSV99810090; called by muse, mutect2
- CD1D | c.624G>C p.W208C | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100939541; called by muse, mutect2, varscan2
- CDS1 | c.227T>G p.L76R | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99880382; called by muse, mutect2, varscan2
- CLCA1 | c.2387T>G p.I796S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.71); catalogued as COSV99321902; called by muse, mutect2, varscan2
- CLHC1 | c.743G>T p.W248L | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100811471; called by muse, mutect2, varscan2
- CMKLR1 | c.302T>C p.M101T (on ENST00000312143 / NM_001142344.2; = p.M99T on NM_004072.3) | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as rs1374727525, COSV100379197; called by muse, mutect2, varscan2
- DSP | c.6523C>A p.P2175T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101131180; called by muse, mutect2, varscan2
- EMC2 | c.557C>A p.P186Q | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99623871; called by muse, mutect2, varscan2
- GOLGA1 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV100332222; called by muse, mutect2, varscan2
- IGSF1 | c.2431T>C p.Y811H | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV100811733; called by muse, mutect2, varscan2
- IKZF2 | c.760A>C p.N254H | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as COSV100563181; called by muse, varscan2
- LAMA4 | c.2807T>C p.I936T (on ENST00000230538 / NM_001105206.3; = p.I929T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs1554333169, COSV100037588; called by muse, mutect2
- LAMA5 | c.4919C>T p.S1640L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs199963174; called by muse, mutect2, varscan2
- LILRA1 | c.1373C>T p.T458I | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV99251727; called by muse, mutect2
- LRRC66 | c.1223dup p.C409Vfs*20 | Frame Shift Ins (INS) | VAF 34/98 reads (35%) | catalogued as rs752924856; called by mutect2, varscan2
- LTN1 | c.3464A>C p.K1155T | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV100797874; called by muse, varscan2
- MAP3K9 | c.2602G>T p.E868* (on ENST00000554752 / NM_001284230.1; = p.E882* on NM_033141.4) | Nonsense Mutation (SNP) | VAF 15/130 reads (12%) | catalogued as COSV101173459; called by muse, mutect2, varscan2
- MATN4 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | PolyPhen probably damaging (0.996); catalogued as COSV100636874; called by muse, mutect2
- MEP1B | c.1037A>G p.Y346C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs760530908, COSV99328640; called by muse, mutect2, varscan2
- MID1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | catalogued as CD041164, COSV100452221; called by muse, mutect2, varscan2
- MRPL58 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100042956, COSV100043077; called by muse, mutect2, varscan2
- NAV3 | c.6254C>A p.A2085E (on ENST00000397909 / NM_001024383.2; = p.A2063E on NM_014903.6) | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.848); catalogued as COSV99886899; called by muse, mutect2
- NR3C2 | c.2235T>G p.I745M | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100678671; called by muse, mutect2, varscan2
- OR2AK2 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 67/182 reads (37%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.799); catalogued as rs750249401, COSV63552487; called by muse, mutect2, varscan2
- PCDHGA10 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); catalogued as rs893578830, COSV99530558; called by muse, mutect2, varscan2
- PKD2L1 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100559298; called by muse, mutect2, varscan2
- PLXNA3 | c.3215T>C p.I1072T | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.13); PolyPhen benign (0.302); catalogued as COSV100859797; called by muse, mutect2, varscan2
- POLG | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs74382477, COSV51519376; ClinVar: uncertain significance / likely benign; called by muse, varscan2
- PROC | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as CM961151, COSV99300647; called by muse, mutect2, varscan2
- RASA3 | c.173+1G>A p.X58_splice | Splice Site (SNP) | VAF 31/99 reads (31%) | catalogued as COSV100479762; called by muse, mutect2, varscan2
- SLC5A11 | c.582T>C p.A194= | Splice Region (SNP) | VAF 18/55 reads (33%) | catalogued as COSV100762665; called by muse, mutect2, varscan2
- SOX5 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58630532; called by muse, mutect2, varscan2
- SUB1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.133); catalogued as COSV99421525; called by muse, mutect2, varscan2
- TLN2 | c.2140C>G p.L714V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100167966; called by muse, mutect2, varscan2
- TMTC2 | c.1747A>G p.T583A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV100337544; called by muse, mutect2
- UNC5C | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV101497782; called by muse, mutect2, varscan2
- VHL | c.242_243insA p.R82Afs*50 | Frame Shift Ins (INS) | VAF 10/21 reads (48%) | catalogued as COSV99845675; called by mutect2, pindel, varscan2
- VN1R1 | c.37A>C p.M13L | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV100320583; called by muse, mutect2, varscan2
- BAMBI | c.379dup p.Y127Lfs*4 | Frame Shift Ins (INS) | VAF 10/62 reads (16%) | called by mutect2, varscan2
- BAMBI | c.380delinsTT p.Y127Ffs*4 | Frame Shift Ins (INS) | VAF 15/79 reads (19%) | called by mutect2*, pindel, varscan2*
- CPEB3 | c.1222dup p.N408Kfs*6 | Frame Shift Ins (INS) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- MAX | c.184_190del p.Q62* | Frame Shift Del (DEL) | VAF 51/136 reads (38%) | called by mutect2, pindel, varscan2
- PBRM1 | c.1225del p.Y409Tfs*29 | Frame Shift Del (DEL) | VAF 45/121 reads (37%) | called by mutect2, pindel, varscan2
- RECK | c.2170del p.C724Vfs*109 | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel, varscan2
- SETD2 | c.7143del p.S2382Lfs*29 | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | called by pindel, varscan2
- TMEM251 | c.2dup p.M1? | Frame Shift Ins (INS) | VAF 27/61 reads (44%) | called by mutect2, pindel, varscan2
- TTL | c.385_395delinsCC p.E129_L132delinsP | In Frame Del (DEL) | VAF 21/92 reads (23%) | called by pindel, varscan2*
- ZNF280D | c.2259+1dup p.X753_splice | Splice Site (INS) | VAF 180/644 reads (28%) | called by mutect2, varscan2
- AGTR2 | c.429C>T p.Y143= | Silent (SNP) | VAF 67/198 reads (34%) | catalogued as COSV100903530; called by muse, mutect2, varscan2
- DOT1L | c.4497C>T p.S1499= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs370187220; called by muse, mutect2, varscan2
- HOOK2 | c.2073G>C p.L691= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV99244203; called by muse, mutect2, varscan2
- MALT1 | c.1044A>T p.I348= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV100618582; called by muse, mutect2, varscan2
- PTCD2 | c.423C>T p.Y141= | Silent (SNP) | VAF 45/260 reads (17%) | catalogued as rs770861070, COSV57339088; called by muse, mutect2, varscan2
- PTCHD3 | c.1737T>A p.T579= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as COSV101438816; called by muse, mutect2, varscan2
- RASGEF1C | c.1038C>T p.R346= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as rs545722886, COSV63178648; called by muse, mutect2, varscan2
- RGS11 | c.303G>A p.T101= (on ENST00000397770 / NM_183337.3; = p.T80= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs1460625933, COSV99395605; called by muse, mutect2, varscan2
- RSKR | c.273C>G p.L91= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1375044107, COSV99971921; called by muse, mutect2, varscan2
- STX11 | c.12G>A p.R4= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV100845461; called by muse, mutect2, varscan2
- TTC37 | c.3420G>A p.L1140= | Silent (SNP) | VAF 85/318 reads (27%) | catalogued as COSV100706352; called by muse, mutect2, varscan2
- SLC28A1 | c.461+300T>A | Intron (SNP) | VAF 11/61 reads (18%) | catalogued as COSV99722553; called by muse, mutect2, varscan2
